Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAII, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAII-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 4.5 cm; angio-invasion present; no invasion in rete testis. Tumor confined to testis in available slides.

Date of procurement (= date of orchidectomy):

ICD-O 3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 1f9ccbdf-61a3-4c9c-a3fa-df3be80932c9 (TCGA-2G-AAII-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).